Somatic mutation profile of tumor specimen C3N-00546-01 (aliquot CPT0067070006) from CPTAC case C3N-00546, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 58.8 years (21,464 days).
Specimen C3N-00546-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee58aa11-4bef-4de5-b232-b9d2f0270d39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00546-71 (Blood Derived Normal), aliquot CPT0067190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb58fd5d-b1b1-41e9-8767-509382637e77

The open-access MAF lists 190 somatic variants for this specimen: 128 protein-altering or splice-affecting, 38 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 38, Intron 9, Frame Shift Del 8, Nonsense Mutation 6, Frame Shift Ins 4, RNA 4, 3'UTR 4, 5'Flank 3, 5'UTR 3, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2155G>A p.G719S | Missense Mutation (SNP) | VAF 251/602 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28929495, COSV51766606, COSV51767289; ClinVar: pathogenic / not provided / drug response; called by muse, mutect2, varscan2
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 171/393 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1094C>G p.S365* | Nonsense Mutation (SNP) | VAF 79/414 reads (19%) | catalogued as rs864622107, CM119586, COSV99049860; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 87/308 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AIMP2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 198/445 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV99552257; called by muse, mutect2, varscan2
- AK5 | c.1487G>A p.R496H (on ENST00000354567 / NM_174858.3; = p.R470H on NM_012093.4) | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs777102302, COSV60967312; called by muse, mutect2, varscan2
- ARAP2 | c.3119A>G p.D1040G | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs995374361; called by muse, mutect2
- ATP13A2 | c.844A>C p.S282R | Missense Mutation (SNP) | VAF 104/570 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.599); catalogued as CM098008; called by muse, varscan2
- ATP1A4 | c.2297C>T p.T766M | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs755083373; called by muse, mutect2, varscan2
- BCL11A | c.1692del p.D564Efs*32 (on ENST00000335712 / NM_001365609.1; = p.D598Efs*32 on NM_018014.4) | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as COSV100185327; called by mutect2, pindel, varscan2
- C4orf17 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs373542741; called by muse, mutect2, varscan2
- COL1A1 | c.1778G>C p.G593A | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM070701; called by muse, mutect2, varscan2
- CT47A6 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 119/629 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.188); catalogued as rs754387926, COSV70031670; called by muse, mutect2, varscan2
- DENND1A | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 66/341 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1243663517, COSV65354952; called by muse, mutect2, varscan2
- DYNC1H1 | c.8455G>C p.E2819Q | Missense Mutation (SNP) | VAF 87/436 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99081000; called by muse, mutect2, varscan2
- ECH1 | c.117del p.E40Rfs*6 | Frame Shift Del (DEL) | VAF 39/234 reads (17%) | catalogued as COSV55490214; called by mutect2, pindel, varscan2
- EXOSC6 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV55747167; called by muse, mutect2
- FAM193A | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.063); catalogued as rs768323216; called by muse, mutect2, varscan2
- FKBP3 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV53531956; called by muse, mutect2, varscan2
- FSCN3 | c.487A>G p.M163V | Missense Mutation (SNP) | VAF 109/216 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs757967612; called by muse, mutect2, varscan2
- GAL3ST3 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745551285, COSV61749016, COSV61749254; called by muse, mutect2, varscan2
- GBP3 | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 22/203 reads (11%) | catalogued as COSV52518660; called by muse, mutect2
- HIPK4 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs146668696; called by muse, mutect2
- INCENP | c.2121_2150del p.R708_R717del (on ENST00000394818 / NM_001040694.2; = p.R704_R713del on NM_020238.3) | In Frame Del (DEL) | VAF 51/343 reads (15%) | catalogued as rs751876282; called by muse*, mutect2, varscan2*
- KCNV1 | c.1183T>C p.Y395H | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52084969; called by muse, mutect2, varscan2
- LRFN5 | c.1701C>A p.S567R | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV53251137, COSV99983365; called by muse, mutect2, varscan2
- MFAP3 | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs377593609; called by muse, mutect2, varscan2
- MYH9 | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs762745890, COSV53392383; called by muse, mutect2, varscan2
- MYO18B | c.4166G>C p.G1389A | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs752237650; called by muse, mutect2, varscan2
- MYO7A | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs781922871, COSV68685692; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEFM | c.2340G>C p.E780D | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV55332218; called by muse, mutect2, varscan2
- NOS1 | c.3909G>T p.Q1303H | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100499980; called by muse, mutect2, varscan2
- OR11G2 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1224442763, COSV62131736; called by muse, mutect2, varscan2
- OR11L1 | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 23/323 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1475636739, COSV100869465; called by muse, mutect2
- OR14A2 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.622); catalogued as COSV99057563; called by muse, mutect2, varscan2
- OR2G2 | c.515G>T p.C172F | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60742187; called by muse, mutect2, varscan2
- PCDH8 | c.2213G>T p.G738V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV58812470; called by muse, mutect2, varscan2
- PCDHA3 | c.773del p.G258Vfs*3 | Frame Shift Del (DEL) | VAF 44/228 reads (19%) | catalogued as rs781928400; called by mutect2, pindel, varscan2
- PTCD1 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 59/804 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs374882141; called by muse, mutect2
- PTPRQ | c.3370G>T p.G1124C (on ENST00000616559; = p.G1082C on NM_001145026.2) | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758331777; called by muse, mutect2, varscan2
- RALGAPA2 | c.5560G>C p.E1854Q | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52503578; called by muse, mutect2, varscan2
- RNF19A | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 60/477 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as rs779636826, CM162933; called by muse, mutect2, varscan2
- SAP130 | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.426); catalogued as COSV52094817; called by muse, mutect2, varscan2
- SETD2 | c.3651G>A p.W1217* | Nonsense Mutation (SNP) | VAF 36/201 reads (18%) | catalogued as COSV57439760, COSV57456184; called by muse, mutect2, varscan2
- SLC8A3 | c.2267C>T p.A756V (on ENST00000381269 / NM_183002.3; = p.A754V on NM_033262.4) | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs1382909462; called by muse, mutect2, varscan2
- SRPK3 | c.240C>A p.H80Q | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV54208850; called by muse, mutect2, varscan2
- TBXA2R | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 229/695 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368237865; called by muse, mutect2, varscan2
- TG | c.5768del p.P1923Qfs*19 | Frame Shift Del (DEL) | VAF 77/670 reads (11%) | catalogued as CM160955; called by mutect2, pindel, varscan2
- TMEM219 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 25/457 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV54243891, COSV54244506; called by muse, mutect2
- TRAPPC12 | c.409del p.R137Afs*44 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | catalogued as COSV60852306; called by mutect2, pindel, varscan2
- TRIM9 | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as rs1474078106; called by muse, varscan2
- TRPV4 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 108/493 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs753813565; called by muse, mutect2, varscan2
- VAV3 | c.1630T>C p.C544R | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769211364; called by muse, mutect2, varscan2
- XYLT1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757356673, COSV54477491; called by muse, mutect2, varscan2
- ADAMTS16 | c.2662G>T p.G888* | Nonsense Mutation (SNP) | VAF 15/197 reads (8%) | called by muse, mutect2
- AKAP3 | c.1063G>T p.V355F | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ANHX | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- APC2 | c.6619C>A p.P2207T | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARHGEF40 | c.3331C>T p.P1111S | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ARSG | c.26dup p.L9Ffs*37 | Frame Shift Ins (INS) | VAF 30/151 reads (20%) | called by mutect2, pindel, varscan2
- ASS1 | c.493A>G p.K165E | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.017); called by muse, mutect2
- ATP10B | c.2839-2A>G p.X947_splice | Splice Site (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2
- CADPS2 | c.1583A>G p.K528R | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- CD1C | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 53/430 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CDH11 | c.1169A>G p.H390R | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2
- CFAP44 | c.3304G>T p.G1102W | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CNTNAP4 | c.2167del p.T723Lfs*4 | Frame Shift Del (DEL) | VAF 38/220 reads (17%) | called by mutect2, pindel, varscan2
- CPNE3 | c.571T>C p.W191R | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.3296T>A p.V1099E (on ENST00000297405 / NM_001363185.1; = p.V995E on NM_052900.3) | Missense Mutation (SNP) | VAF 71/445 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CWH43 | c.1163A>T p.K388M | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DDX60 | c.3499_3502dup p.V1168Afs*5 | Frame Shift Ins (INS) | VAF 27/132 reads (20%) | called by mutect2, pindel, varscan2
- DNAH1 | c.8497A>T p.K2833* | Nonsense Mutation (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2
- DNAJC6 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DST | c.19686dup p.V6563Cfs*30 (on ENST00000361203 / NM_001374722.1; = p.V4260Cfs*30 on NM_015548.5) | Frame Shift Ins (INS) | VAF 42/261 reads (16%) | called by pindel, varscan2
- EPHA3 | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ESRRG | c.590G>C p.G197A | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- EXOC5 | c.601_602insG p.T201Sfs*8 | Frame Shift Ins (INS) | VAF 36/264 reads (14%) | called by mutect2, pindel*, varscan2
- F5 | c.3671C>G p.P1224R | Missense Mutation (SNP) | VAF 79/556 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- FOXL1 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- FTMT | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- FUBP1 | c.162T>A p.N54K | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- GINS3 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- HEPH | c.2369C>A p.T790N (on ENST00000343002; = p.T523N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- HERC1 | c.7339G>C p.D2447H | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- IGHA2 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.182); called by muse, mutect2
- IGSF1 | c.3050C>A p.T1017N | Missense Mutation (SNP) | VAF 82/324 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- KDR | c.1684A>T p.T562S | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- KMT2C | c.3098A>T p.H1033L | Missense Mutation (SNP) | VAF 129/261 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LGR6 | c.2715G>T p.Q905H (on ENST00000367278 / NM_001017403.1; = p.Q853H on NM_021636.3) | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- LIN54 | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- LOXL1 | c.925T>A p.W309R | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- LRRC49 | c.687G>C p.L229F | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MLST8 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- MRC1 | c.2486A>T p.K829M | Missense Mutation (SNP) | VAF 93/487 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MUC16 | c.2389C>A p.P797T | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYO1F | c.2890G>A p.G964R | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO5A | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- NBPF6 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC4 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, varscan2
- NPHS1 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 107/724 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR1S2 | c.620T>A p.I207N | Missense Mutation (SNP) | VAF 50/365 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PDHA2 | c.1127G>C p.R376P | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- PDZRN3 | c.1021A>T p.R341W | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- PLEKHO2 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- POSTN | c.2411T>C p.I804T | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RAI1 | c.5275G>T p.G1759C | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- RARA | c.673T>A p.W225R | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP8NL | c.1266_1276delinsA p.G423Rfs*13 | Frame Shift Del (DEL) | VAF 27/151 reads (18%) | called by pindel, varscan2*
- RBFOX1 | c.419T>A p.F140Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- RPL27A | c.385_387del p.F129del | In Frame Del (DEL) | VAF 54/278 reads (19%) | called by pindel, varscan2
- RWDD3 | c.680A>C p.E227A | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SELP | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETD1B | c.5519G>T p.G1840V | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFSWAP | c.1747A>G p.I583V | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SI | c.2348C>G p.P783R | Missense Mutation (SNP) | VAF 65/355 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SUPT20HL1 | c.2463C>G p.I821M | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- SYNPO2 | c.3470T>A p.V1157E | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- TENM2 | c.2172C>A p.S724R (on ENST00000518659 / NM_001122679.2; = p.S492R on NM_001080428.3) | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- VIT | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- XRN1 | c.422C>G p.A141G | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- YLPM1 | c.6285del p.K2096Rfs*21 | Frame Shift Del (DEL) | VAF 46/211 reads (22%) | called by mutect2, pindel, varscan2
- ZEB2 | c.2111G>C p.R704T | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZFHX2 | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.13); called by muse, mutect2, varscan2
- ZNF419 | c.579G>T p.R193S | Missense Mutation (SNP) | VAF 72/371 reads (19%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF419 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 71/375 reads (19%) | called by muse, mutect2, varscan2
- ZNF658 | c.747A>T p.R249S | Missense Mutation (SNP) | VAF 58/441 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZNF670 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ZSCAN22 | c.1396T>G p.C466G | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACTR3 | c.651A>G p.P217= | Silent (SNP) | VAF 21/176 reads (12%) | called by muse, mutect2, varscan2
- ANO3 | c.1917G>T p.L639= | Silent (SNP) | VAF 34/232 reads (15%) | catalogued as COSV56805598; called by muse, mutect2, varscan2
- ARSA | c.1323C>T p.Y441= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- ASTN1 | c.186G>A p.S62= | Silent (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- CACNA1S | c.4128T>C p.F1376= | Silent (SNP) | VAF 90/570 reads (16%) | called by muse, mutect2, varscan2
- CCND2 | c.249C>T p.Y83= | Silent (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- CD1C | c.741G>T p.L247= | Silent (SNP) | VAF 53/427 reads (12%) | catalogued as COSV63806146; called by muse, mutect2, varscan2
- CUL9 | c.1362G>A p.G454= | Silent (SNP) | VAF 29/131 reads (22%) | called by muse, mutect2, varscan2
- FAM187A | c.672G>T p.R224= | Silent (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- FLT4 | c.2355C>T p.I785= | Silent (SNP) | VAF 85/454 reads (19%) | called by muse, varscan2
- HFM1 | c.624T>C p.N208= | Silent (SNP) | VAF 63/241 reads (26%) | called by muse, mutect2, varscan2
- INTS1 | c.2964G>A p.V988= | Silent (SNP) | VAF 31/216 reads (14%) | called by muse, mutect2, varscan2
- KCNH5 | c.1542C>A p.S514= | Silent (SNP) | VAF 76/351 reads (22%) | catalogued as COSV59769577; called by muse, mutect2, varscan2
- KIAA1549L | c.3111G>A p.P1037= (on ENST00000321505; = p.P1334= on NM_012194.3) | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs1243221356, COSV55776409; called by muse, mutect2
- LCP1 | c.243A>G p.L81= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as rs1389278583; called by muse, mutect2
- LPCAT4 | c.1176G>T p.V392= | Silent (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- MARF1 | c.4578G>A p.K1526= | Silent (SNP) | VAF 53/512 reads (10%) | called by muse, mutect2
- MRC2 | c.597C>T p.H199= | Silent (SNP) | VAF 22/149 reads (15%) | catalogued as rs370235388; called by muse, mutect2, varscan2
- NEFH | c.819G>A p.E273= | Silent (SNP) | VAF 65/296 reads (22%) | catalogued as rs917756240, COSV60220162, COSV60220757; called by muse, mutect2, varscan2
- NME7 | c.612A>T p.A204= | Silent (SNP) | VAF 48/333 reads (14%) | catalogued as rs745878837; called by muse, mutect2, varscan2
- NOCT | c.429C>T p.I143= | Silent (SNP) | VAF 45/225 reads (20%) | catalogued as rs1322601884; called by muse, mutect2, varscan2
- NPHP4 | c.2910G>T p.L970= | Silent (SNP) | VAF 57/266 reads (21%) | called by muse, mutect2, varscan2
- OSCP1 | c.36C>T p.N12= | Silent (SNP) | VAF 22/176 reads (13%) | catalogued as rs751627554; called by muse, mutect2, varscan2
- PCNX2 | c.4248C>T p.G1416= | Silent (SNP) | VAF 58/552 reads (11%) | catalogued as rs747167792, COSV50794497; called by muse, mutect2
- PRUNE2 | c.7488A>C p.A2496= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- SEC22C | c.681T>C p.F227= | Silent (SNP) | VAF 24/158 reads (15%) | called by muse, mutect2, varscan2
- SLIT3 | c.1752G>A p.Q584= | Silent (SNP) | VAF 19/219 reads (9%) | called by muse, mutect2
- SORL1 | c.4053C>T p.G1351= | Silent (SNP) | VAF 45/237 reads (19%) | catalogued as rs149859900; called by muse, mutect2, varscan2
- SPATA12 | c.414G>A p.E138= | Silent (SNP) | VAF 28/366 reads (8%) | catalogued as rs1201407373; called by muse, mutect2
- SRGAP3 | c.888C>T p.H296= | Silent (SNP) | VAF 56/316 reads (18%) | catalogued as rs748814269, COSV64532208; called by muse, mutect2, varscan2
- STON2 | c.51C>A p.S17= | Silent (SNP) | VAF 36/162 reads (22%) | called by muse, mutect2, varscan2
- STYXL2 | c.2512C>A p.R838= | Silent (SNP) | VAF 37/240 reads (15%) | catalogued as COSV54810451; called by muse, mutect2, varscan2
- TP53INP2 | c.372G>T p.P124= | Silent (SNP) | VAF 54/234 reads (23%) | catalogued as rs1353488596; called by mutect2, varscan2
- TRPC4AP | c.324G>A p.E108= | Silent (SNP) | VAF 44/192 reads (23%) | called by muse, mutect2, varscan2
- UBQLN2 | c.849A>G p.A283= | Silent (SNP) | VAF 55/121 reads (45%) | catalogued as rs755246528; called by muse, mutect2, varscan2
- WDR97 | c.4458G>T p.A1486= | Silent (SNP) | VAF 45/173 reads (26%) | called by muse, mutect2, varscan2
- ZBTB37 | c.1221C>A p.G407= | Silent (SNP) | VAF 29/302 reads (10%) | called by muse, mutect2
- ZNF614 | c.474T>C p.F158= | Silent (SNP) | VAF 35/333 reads (11%) | called by muse, mutect2, varscan2
- AC022415.2 | c.*3444G>A | 3'UTR (SNP) | VAF 51/176 reads (29%) | called by muse, mutect2, varscan2
- ALDH3B1 | c.*157C>T | 3'UTR (SNP) | VAF 43/253 reads (17%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501564 del AA | 5'Flank (DEL) | VAF 36/163 reads (22%) | called by mutect2, pindel, varscan2
- C5orf60 | n.107C>T | RNA (SNP) | VAF 60/339 reads (18%) | catalogued as rs866745086, COSV101495106, COSV71508672; called by muse, mutect2, varscan2
- CCDC177 | c.*687C>T | 3'UTR (SNP) | VAF 35/194 reads (18%) | called by muse, mutect2, varscan2
- CHN2 | c.654+3574G>C | Intron (SNP) | VAF 110/282 reads (39%) | called by muse, mutect2, varscan2
- ELAVL4 | c.9+765T>C | Intron (SNP) | VAF 44/237 reads (19%) | catalogued as rs781296512; called by muse, varscan2
- FUT6 | c.*31del | 3'UTR (DEL) | VAF 315/1003 reads (31%) | called by mutect2, pindel, varscan2
- GALT | c.820+32G>A | Intron (SNP) | VAF 50/753 reads (7%) | catalogued as rs983255120; called by muse, mutect2
- HSPG2 | c.3303-31T>G | Intron (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- ITPKB | c.1932+27623G>T | Intron (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- ITPR2 | c.-18T>C | 5'UTR (SNP) | VAF 52/255 reads (20%) | called by muse, mutect2, varscan2
- KLF6 | chr10:3785281 del C | 5'Flank (DEL) | VAF 25/133 reads (19%) | called by mutect2, pindel
- LASP1 | c.-56C>G | 5'UTR (SNP) | VAF 15/193 reads (8%) | catalogued as COSV58804722; called by muse, mutect2
- LILRB5 | c.1256-144G>T | Intron (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- MUC19 | n.5715G>T | RNA (SNP) | VAF 41/211 reads (19%) | catalogued as rs541050343; called by muse, mutect2, varscan2
- RDH13 | c.658+89C>T | Intron (SNP) | VAF 32/466 reads (7%) | catalogued as rs751125293; called by muse, mutect2
- RPS11 | chr19:49500817 A>G | 3'Flank (SNP) | VAF 15/58 reads (26%) | catalogued as rs1413039185; called by muse, mutect2, varscan2
- SHISAL2B | c.192-1361A>T | Intron (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- SLC16A6P1 | n.565A>T | RNA (SNP) | VAF 76/464 reads (16%) | called by muse, mutect2, varscan2
- SOX8 | chr16:981267 C>G | 5'Flank (SNP) | VAF 33/225 reads (15%) | called by muse, mutect2, varscan2
- TSNAXIP1 | c.-298G>T | 5'UTR (SNP) | VAF 56/289 reads (19%) | called by muse, mutect2, varscan2
- WDR49 | c.-66+19839G>T | Intron (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- ZNF137P | n.1661T>G | RNA (SNP) | VAF 36/426 reads (8%) | catalogued as rs781027251; called by muse, mutect2
